Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5698, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5698-01A (Primary Tumor).

[page 1 of 2]
HISTORY: History of right kidney lesion.
PRE-OP DIAGNOSIS: Right kidney lesion.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Right nephrectomy.

ADDENDA:
Addendum

SPECIAL PROCEDURE REPORT
MOLECULAR ANATOMIC PATHOLOGY FLUORESCENCE IN SITU HYBRIDIZATION ANALYSIS

Comment: Fluorescent in-situ hybridization (FISH) tests show monosomy of chromosome 17 in 35% of the tumor cells. This FISH profile is consistent with a diagnosis of a conventional clear cell renal cell carcinoma.

Specimen type: Renal tumor.

Result:

Paraffin Block and histology	Centromere Probe	Copy No. 1	Copy No. 2	Copy No. 3	Copy No. 4 and 4+
	CEP1	6(9.2%)	59(90.8%)		
	CEP7	12(20.0%)	48(80.0%)		
	CEP17	21(35.0%)	39(65.0%)		

Abnormality detected: Monosomy of chromosome 17 in 35% of the tumor cells

Interpretation guidelines:

Chromosomal losses are considered significant if present in greater than 30% of cells. The loss is indeterminate if present in 20-30% of cases. The loss is considered artifactual if seen in less than 20% of cases.

Chromosomal gains are considered significant if present in greater than 20% of cells. The gain is considered artifactual if seen in less than 20% of cases.

Probes used: CEP1 (1p11.1q11.1), CEP7 (7p11.1q11.1), CEP17 (17p11.1q11.1).

At least 25 cells are analyzed. The signal distribution for targeted foci of renal carcinoma is recorded. If the test results are not consistent with the clinical findings, and/or diagnostic, a consultation between pathologist and treating physician is warranted.

FINAL DIAGNOSIS:

PART 1:

KIDNEY, RIGHT, COMPLETION NEPHRECTOMY –

- A. RENAL PARENCHYMA WITH NO EVIDENCE OF RESIDUAL TUMOR.**
- B. URETER WITH URETERITIS CYSTICA.**
- C. VASCULAR AND URETERAL MARGINS WITH NO EVIDENCE OF TUMOR.**
- D. THE ADRENAL GLAND IS NOT SUBMITTED.**

PART 2:

KIDNEY, RIGHT RENAL MASS, PARTIAL NEPHRECTOMY –

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN NUCLEAR GRADE III/IV, 4.5 CM IN GREATEST DIMENSION.**
- B. THE NEOPLASM IS CONFINED WITHIN THE RENAL PARENCHYMA, WITH NO INVASION OF THE RENAL SINUS OR PERINEPHRIC ADIPOSE TISSUE.**
- C. ANGIOLYMPHATIC INVASION IS NOT IDENTIFIED.**
- D. ALL SURGICAL MARGINS ARE FREE OF TUMOR (See Part 1 above).**
- E. PATHOLOGIC STAGE: pTNM = pT1b Nx Mx.**
- F. NON-NEOPLASTIC KIDNEY WITH NO SIGNIFICANT PATHOLOGIC ABNORMALITY.**

[page 2 of 2]
SYNOPTIC - PRIMARY Kidney/Renal Pelvis/Ureter TUMORS

- A. Side: 1 1. Right 2. Left
- B. Location: 1
1. Kidney (parenchyma - cortex/medulla)
2. Kidney (pelvis)
3. Ureter
4. Kidney and ureter
- C. Procedure: 3
1. Partial nephrectomy
2. Simple nephrectomy
3. Radical nephrectomy
4. Ureterectomy
5. Other
- D. Size of neoplasm (maximum dimension; if multicentric, size of largest mass): 4.5 cm
- E. Type of malignant neoplasm: 1
1. Renal cell carcinoma, clear cell type (includes non-papillary granular cell RCC)
2. Renal cell carcinoma, chromophil cell type (papillary RCC, no clear cell component)
3. Renal cell carcinoma, chromophobe cell type
4. Renal cell carcinoma, oncocytic
5. Renal cell carcinoma, sarcomatoid
6. Collecting duct carcinoma
7. Urothelial carcinoma, TCCa (non-invasive)
8. Urothelial carcinoma, TCCa (invasive ± in-situ)
9. Urothelial carcinoma, squamous carcinoma
10. Urothelial carcinoma, adenocarcinoma
11. Urothelial carcinoma, small cell/neuroendocrine carcinoma
12. Urothelial carcinoma, mixed
13. Juxtaglomerular cell tumor
14. Wilms' tumor
15. Rhabdoid tumor
16. Clear cell sarcoma
17. Congenital mesoblastic nephroma
18. Sarcoma (non-clear cell)
19. Lymphoma/leukemia
20. Other
- F. Histologic grade
F1. Fuhrman grade (for RCC; grades 1-4): 3
F2. Ash grade (grade 1-4): N/A
F3. WHO grade (grade 1-3): N/A (for TCCa)
F4. [REDACTED]
F5. Other malignant neoplasms (grades 1-3): N/A
- G. Non-neoplastic and other conditions: N/A
1. Glomerulopathy
2. Interstitial nephritis
3. Pyelonephritis
4. Nephrolithiasis
5. Papillary necrosis
6. Chronic parenchymal disease
7. Other
- H. Margins of resection: 2 1. Positive 2. Negative
- I. Mitotic activity: 0 per 10 high power fields
- J. Angiolymphatic invasion
J1. Macroscopic (e.g., renal vein thrombus): 2 1. Positive 2. Negative
J2. Microscopic: 2 1. Positive 2. Negative
- K. Number of positive lymph nodes: N/A
- L. Total number of lymph nodes examined: 0
- M. Extracapsular spread of lymph node metastases: N/A
1. Yes 2. No
- N. Adrenal gland:
N1. Present 2 1. Yes 2. No
N2. Involvement by renal neoplasm: 3 1. Yes 2. No 3. Not Applicable
N3. Other adrenal pathology: 3 1. Yes 2. No 3. Not applicable
- O. TNM stage: T 1b N X M X

Source: NCI Genomic Data Commons file 4a3a42ce-6806-409d-9d9b-40dd6caf44e6 (TCGA-B0-5698.FF834AF5-4186-4625-8E6F-349261544FD8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).